Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A62P, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A62P-01A (Primary Tumor).

[page 1 of 4]
Pathology Report:

ICD-O-3
Carcinoma, urothelial NOS
8/20/13
Site ^{path} Bladder NOS C67.9
G6F Posterior wall of bladder
C67.4
7/16/13

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Left pelvic lymph nodes; dissection:

- Four lymph nodes, no tumor present (0/4).

B. Right pelvic lymph nodes; dissection:

- Metastatic prostate adenocarcinoma in one of four lymph nodes (1/4). (See comment).

- No extranodal extension present.

C. Bladder, prostate, seminal vesicles, vas deferens; cystoprostatectomy:

- Urothelial carcinoma of the urinary bladder, high grade, invasive into muscularis propria.
- Urothelial carcinoma in situ involving surface urothelium and von Brunn's nests.
- Margins of resection (soft tissue, urethra, right and left ureter), no tumor present.
- Urinary bladder wall with ulceration, necrosis and foreign body giant cell reaction consistent with previous resection site.
- Extensive cystitis cystica.
- See pathologic parameters.

- Prostatic adenocarcinoma, Gleason score 7 (4+3), with a small component of Gleason grade 5.

- Extraprostatic extension present.
- Margins of resection positive for carcinoma.
- Seminal vesicles and vasa deferentia, no tumor present.
- High grade prostatic intraepithelial neoplasia (PIN).
- See pathologic parameters.

D. Left distal ureter stitch; resection:

- Segment of ureter, no tumor present.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Flat urothelial carcinoma
2. Grade of tumor: High grade
3. Depth of invasion: Muscularis propria
4. Tumor distribution: Multifocal 3 x 2.7 cm the largest size
Right lateral wall
Anterior wall

[page 2 of 4]
Posterior wall

5. Ureteral margins: Negative
6. Distal urethral margin: Negative
7. Soft tissue margin or serosa: Negative
8. Lymph nodes: Eight lymph nodes, no urothelial carcinoma present (0/8).
9. pTNM: pT2bN0

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Radical Prostatectomy Pathologic Parameters

1. Gleason Score: 7 (4+3) with a small component of Gleason grade 5
2. Perineural Invasion: Present
3. Tumor Location:
Peripheral zone - Right and left, Transition zone
4. Tumor Volume Estimate: 60%
5. High-grade P.I.N.: Multifocal
6. Seminal Vesicles: Negative
7. Extraprostatic extension: Present
8. Peripheral Margin: Negative
9. Distal (apical) Margin: Positive
10. Proximal (basilar) Margin: N/A
11. Regional Lymph Nodes (right and left): Metastatic prostate adenocarcinoma in one of eight lymph nodes (1/8)
12. pTNM: pT3aN0

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for prostatectomy of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Comment

Part B: The metastatic carcinoma is represented by a single gland that is positive for Cam5.2. Immunohistochemical stain PSA is non-contributory due to the absence of the malignant gland on a section submitted for immunohistochemistry.

Interpretation performed by the Attending Pathologist and reviewed with the

[page 3 of 4]
Clinical History:

The patient is a year-old male with bladder cancer undergoing cystectomy.

Specimens Received:

A: Left pelvic lymph nodes

B: Right pelvic lymph nodes

C: Bladder, prostate, seminal vesicles, vas deferens

D: Left distal ureter stitch

Gross Description:

The specimens are received in four containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "left pelvic lymph nodes". Received fresh and placed in formalin is an aggregate of lobulated yellow fibroadipose tissue measuring 7.2 x 5.4 x 1.3 cm. The specimen is dissected for lymph node candidates. 5 lymph node candidates are identified measuring 0.5-4.5 cm in greatest dimension. The lymph node candidates are entirely submitted as follows:

A1: 2 lymph node candidates

A2: One lymph node candidate, bisected

A3-A4: One lymph node candidate, sectioned

A5-A8: One lymph node candidate, sectioned

B. The second container is additionally identified as, "right pelvic lymph nodes". Received fresh and placed in formalin is an aggregate of lobulated yellow fibroadipose tissue measuring 7.9 x 7.1 x 1.6 cm. The specimen is dissected for lymph node candidates. 10 lymph node candidates are identified measuring 0.4-7.5 cm in greatest dimension. The lymph node candidates are entirely submitted as follows:

B1: 4 lymph node candidates

B2: 3 lymph node candidates

B3: One lymph node candidate, bisected

B4-B5: One lymph node candidate, sectioned

B6-B8: One lymph node candidate, sectioned

C. The third container is additionally identified as, "3. Bladder, prostate, seminal vesicles, vas deferens ". Received fresh and placed in formalin is a 514.6 g, 20.5 x 11 x 5 cm cystoprostatectomy specimen. The bladder is 8.5 x 8.5 x 5 cm. The right ureteral stump is 4.5 x 0.5 cm and the left ureteral stump is 3 x 0.4 cm. The prostate is 6.3 x 4.8 x 4.8 cm. The right seminal vesicle is 4.3 x 2.3 x 0.9 cm and the right vas deferens is 11.8 x 0.4 cm. The left seminal vesicle is 4.3 x 2.4 x 1 cm and the left vas deferens is 6.5 x 0.5 cm. There are 2 additional detached segments of vas deferens measuring 3.8 x 0.4 cm and 9.8 x

[page 4 of 4]
0.3 cm. The right half of the prostate and bladder is inked blue and the left half is inked black. The bladder and prostate are opened anteriorly along the urethra. The prostate is surrounded by a thin, intact membranous capsule and sectioning demonstrates rubbery, pink-tan, peri-urethral nodularity and a 3.5 x 1 x 1 cm area of firm, tan-white induration along the posterior aspect bilaterally. The seminal vesicles contain dilated cystic spaces filled with tan, gelatinous material. The opened bladder reveals a 3 x 2.7 cm ulceration located in the right posterior/lateral wall with a 5 x 4.2 cm surrounding area of hemorrhagic mucosa. The remaining bladder mucosa is edematous, wrinkled and pink-tan with a uniform 0.2 cm wall thickness. The bladder is serially sectioned to reveal tumor grossly extending to a depth of 1.4 cm which is 2.4 cm from the inked blue margin. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent.

Representative sections are submitted as follows:

- C1: Distal prostatic urethral margin (apex)
- C2: Right and left ureter resection margin (right side is inked blue)
- C3-C5: Prostate apex, shaved and serially sectioned
- C6-C9: Representative right lobe of prostate from apex to base
- C10-C13: Representative left lobe of prostate submitted from apex to base
- C14: Right seminal vesicle and vas deferens
- C15: Left seminal vesicle and vas deferens
- C16: Uninvolved bladder mucosa, posterior wall
- C17: Uninvolved bladder mucosa, left lateral wall
- C18: Hemorrhagic mucosa, dome
- C19: Uninvolved bladder mucosa, anterior wall
- C20-C30: Bladder mass/Ulceration (entirely submitted) with the deepest area of invasion in cassette C20 (with inked margin deep to the area of invasion in cassette C21).

D. The fourth container is additionally identified as, "left distal ureter stitch on non-margin side". Received fresh and placed in formalin is a rubbery white-tan tubular structure measuring 0.9 cm in length and 0.6 cm in diameter. There is a stitch designating the non-margin side. The margin side is shaved and submitted in D1.

Source: NCI Genomic Data Commons file d0f03002-4b46-4d8d-8147-e832ee902ddd (TCGA-FD-A62P.491E768C-1E7C-4461-BFF7-BA846758B39F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).